Somatic mutation profile of tumor specimen TCGA-17-Z011-01A (aliquot TCGA-17-Z011-01A-01W-0746-08) from TCGA case TCGA-17-Z011, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z011-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 257c51d5-e3bf-4c3f-9cd6-acf827764784.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z011-11A (Solid Tissue Normal), aliquot TCGA-17-Z011-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/401b2d00-7678-4c47-9468-73debf61a5f2

The open-access MAF lists 112 somatic variants for this specimen: 83 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 27, Nonsense Mutation 5, Splice Site 3, Intron 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4033G>T p.E1345* | Nonsense Mutation (SNP) | VAF 35/69 reads (51%) | catalogued as rs1211642532, CM994565, COSV57322919; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 165/525 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by muse, mutect2, varscan2
- ACP6 | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV65076383; called by muse, varscan2
- ADA2 | c.186G>T p.R62S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.035); catalogued as rs1555887378; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP44 | c.412C>G p.Q138E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52401681; called by muse, mutect2, varscan2
- BTK | c.1567-1G>T p.X523_splice | Splice Site (SNP) | VAF 72/106 reads (68%) | catalogued as CS163537; called by muse, mutect2, varscan2
- C3AR1 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.232); catalogued as rs1486244130; called by muse, mutect2, varscan2
- CSGALNACT1 | c.454A>G p.T152A | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs1193122458; called by muse, mutect2, varscan2
- CSMD3 | c.4856C>G p.T1619S (on ENST00000297405 / NM_001363185.1; = p.T1515S on NM_052900.3) | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV52176295; called by muse, mutect2, varscan2
- DOCK10 | c.3341C>A p.P1114H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1403565453; called by muse, mutect2, varscan2
- GATM | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV101188328; called by muse, varscan2
- GGH | c.128G>A p.C43Y | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.282); catalogued as rs1463413852, COSV52650455; called by muse, mutect2, varscan2
- GOLIM4 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV58332544; called by muse, mutect2, varscan2
- GPR158 | c.2144G>A p.R715Q | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753599474, COSV66286385; called by muse, mutect2, varscan2
- ILKAP | c.891G>T p.Q297H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV99610909; called by muse, varscan2
- KEAP1 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV50562178, COSV50635540; called by muse, mutect2, varscan2
- LGALS9B | c.280C>A p.Q94K | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.674); catalogued as COSV100163062; called by muse, mutect2, varscan2
- MAGOHB | c.119G>A p.S40N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1441027363; called by muse, mutect2, varscan2
- MARCHF6 | c.2419C>T p.R807C | Missense Mutation (SNP) | VAF 96/576 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs930204888, COSV56883325, COSV56884029; called by muse, mutect2, varscan2
- MCM3 | c.2030G>T p.R677L (on ENST00000229854 / NM_001366374.2; = p.R667L on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1431202474, COSV57717170; called by muse, mutect2, varscan2
- MYH11 | c.1669C>G p.Q557E | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs1439991530; called by muse, mutect2, varscan2
- NAPEPLD | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV58524476; called by muse, mutect2, varscan2
- NCOA5 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs758646068, COSV51642362; called by muse, varscan2
- NCOA5 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 120/242 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs371556953; called by muse, mutect2, varscan2
- NMBR | c.733A>C p.N245H | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs543641531; called by muse, mutect2, varscan2
- OR11L1 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756850738; called by muse, mutect2, varscan2
- OR4C15 | c.374G>T p.C125F (on ENST00000314644; = p.C71F on NM_001001920.2) | Missense Mutation (SNP) | VAF 107/251 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.986); catalogued as rs150289014, COSV58951167; called by muse, mutect2, varscan2
- PLEC | c.10714G>A p.G3572S (on ENST00000322810 / NM_201380.4; = p.G3462S on NM_000445.5) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375044211, COSV59656001; called by muse, mutect2, varscan2
- POM121L12 | c.858G>T p.E286D | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.04); catalogued as COSV68692720; called by muse, mutect2, varscan2
- RAP1GAP | c.733G>T p.V245L | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as rs780639133; called by muse, mutect2, varscan2
- RBFOX1 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1162599045, COSV100304359; called by muse, mutect2, varscan2
- RNF40 | c.1859C>G p.P620R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.225); catalogued as rs1239688042; called by muse, mutect2, varscan2
- SLFN11 | c.312C>A p.Y104* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as COSV57698787; called by muse, mutect2, varscan2
- STS | c.616G>T p.V206L | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as COSV54265732, COSV54271752; called by muse, mutect2, varscan2
- STYXL2 | c.1709C>A p.P570H | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV54805169; called by muse, mutect2, varscan2
- VAX2 | c.452A>T p.Q151L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1553414517; called by muse, mutect2
- ABCC9 | c.1012-1G>A p.X338_splice | Splice Site (SNP) | VAF 32/94 reads (34%) | called by muse, mutect2, varscan2
- ALOXE3 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ARHGEF10L | c.619G>C p.D207H | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC191 | c.1546G>A p.G516S | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CGN | c.2030G>C p.R677P | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- CHD5 | c.4159C>A p.P1387T | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLDN16 | c.277T>C p.F93L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CLEC16A | c.1592A>T p.E531V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- COMMD10 | c.255C>A p.H85Q | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CR2 | c.1753A>T p.T585S | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DLC1 | c.3221G>A p.S1074N (on ENST00000276297 / NM_001348081.2; = p.S637N on NM_006094.5) | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ECEL1 | c.1849G>T p.G617C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERLEC1 | c.647A>C p.H216P | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- GRIK1 | c.1822del p.H608Tfs*17 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel, varscan2
- HEATR3 | c.1598A>T p.Q533L | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HLTF | c.45G>T p.Q15H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IL16 | c.1598C>A p.P533Q | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRX4 | c.736+2T>A p.X246_splice | Splice Site (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- KANSL1L | c.341A>T p.Y114F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KCNS2 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KLHDC4 | c.1411A>T p.M471L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP21-2 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); called by mutect2, varscan2
- LRRIQ1 | c.2468T>C p.L823P | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MADD | c.2405G>C p.G802A | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- METTL14 | c.1054A>G p.T352A | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- MPDZ | c.4468C>A p.Q1490K | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- MYH9 | c.448A>T p.I150F | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- NDRG2 | c.617A>T p.E206V (on ENST00000298687 / NM_001354570.1; = p.E192V on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- OR8H3 | c.326C>A p.T109N | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PDE3A | c.1133G>T p.S378I | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PHLDB2 | c.1773A>T p.E591D | Missense Mutation (SNP) | VAF 117/317 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLS1 | c.640G>T p.G214C | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- PTPRH | c.3007C>A p.L1003I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2
- RABGGTA | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- RANBP6 | c.1669G>T p.E557* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- SACS | c.7832C>A p.T2611K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- SCN10A | c.1593A>T p.E531D | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SEMA5A | c.2779G>T p.G927C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SLC4A4 | c.319C>T p.Q107* (on ENST00000264485 / NM_001098484.3; = p.Q63* on NM_003759.4) | Nonsense Mutation (SNP) | VAF 48/180 reads (27%) | called by muse, mutect2, varscan2
- SPTY2D1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 29/56 reads (52%) | called by muse, mutect2, varscan2
- SV2B | c.355C>A p.L119M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TEAD3 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- TUBA3C | c.319C>G p.H107D | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- USB1 | c.377G>T p.S126I | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- USP50 | c.190A>G p.S64G | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ZNF543 | c.1134G>T p.E378D | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZWINT | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGTPBP1 | c.1767A>G p.L589= (on ENST00000357081 / NM_001330701.2; = p.L549= on NM_015239.2) | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs935868243; called by muse, mutect2, varscan2
- APBB2 | c.1584T>C p.F528= (on ENST00000295974 / NM_001166050.2; = p.F529= on NM_004307.2) | Silent (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- CD1E | c.126T>G p.T42= | Silent (SNP) | VAF 16/270 reads (6%) | catalogued as COSV100937038; called by muse, mutect2
- CDKL2 | c.840G>A p.E280= | Silent (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- CENPW | c.6G>T p.A2= | Silent (SNP) | VAF 52/146 reads (36%) | called by muse, mutect2, varscan2
- DAB2 | c.1107G>T p.S369= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV57914033; called by muse, mutect2, varscan2
- DHX9 | c.456G>A p.K152= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs778356288; called by muse, mutect2, varscan2
- DMP1 | c.1173A>T p.T391= | Silent (SNP) | VAF 91/363 reads (25%) | called by muse, mutect2, varscan2
- HCN1 | c.2032C>T p.L678= | Silent (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- LARP4B | c.381C>T p.L127= | Silent (SNP) | VAF 16/228 reads (7%) | catalogued as rs761532757; called by muse, mutect2
- LRRIQ1 | c.2467C>T p.L823= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as COSV67827638; called by muse, mutect2, varscan2
- MRTFA | c.825C>T p.F275= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as rs768043680; called by muse, varscan2
- NCOA5 | c.615C>T p.V205= | Silent (SNP) | VAF 116/202 reads (57%) | catalogued as rs962969950; called by muse, varscan2
- NCOA5 | c.564C>T p.I188= | Silent (SNP) | VAF 112/204 reads (55%) | called by muse, varscan2
- PCDH15 | c.4983A>C p.S1661= | Silent (SNP) | VAF 23/124 reads (19%) | called by muse, mutect2, varscan2
- PCDH15 | c.78C>A p.G26= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV100216039; called by muse, mutect2, varscan2
- POLDIP3 | c.930A>T p.R310= | Silent (SNP) | VAF 49/152 reads (32%) | called by muse, mutect2, varscan2
- POMC | c.486C>T p.N162= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1459833495, COSV53035102; called by muse, mutect2
- PPP4C | c.381C>T p.Y127= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs778430163; called by muse, mutect2, varscan2
- RNF168 | c.126G>T p.S42= | Silent (SNP) | VAF 41/93 reads (44%) | called by muse, mutect2, varscan2
- SCARF1 | c.1062C>G p.T354= | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- SETBP1 | c.2943A>T p.P981= | Silent (SNP) | VAF 50/147 reads (34%) | called by muse, mutect2, varscan2
- SV2B | c.354C>A p.A118= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV100370460; called by muse, mutect2, varscan2
- XG | c.303C>A p.P101= | Silent (SNP) | VAF 13/18 reads (72%) | called by muse, mutect2, varscan2
- ZC2HC1A | c.573G>A p.P191= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as rs750516008, COSV99804054; called by muse, mutect2, varscan2
- ZCCHC3 | c.789G>T p.T263= | Silent (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- ZNF98 | c.48G>A p.R16= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV100757655, COSV63338341; called by muse, mutect2, varscan2
- ACSL6 | c.993+65G>A | Intron (SNP) | VAF 8/23 reads (35%) | catalogued as rs1279789082; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823000 A>T | 5'Flank (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
